Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13R, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13R-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Multinodular goiter.

Specimens Submitted:

1: Thyroid, thyroidectomy

DIAGNOSIS:

1. **Thyroid, thyroidectomy:**

Tumor Type:

Papillary carcinoma, follicular variant
with oncocytic features

Histologic Grade:

Well differentiated

Mitotic Activity:

Mild to moderate

Tumor Necrosis:

Not identified

Tumor Location:

arising in a parasitic nodule

Tumor Size:

Greatest diameter is 5 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Separate focus of papillary microcarcinoma measuring 0.35cm in right lobe. psammoma bodies also present.

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

ICD-0-3

Carcinoma, papillary of follicular
variant
8340/3
Site: thyroid, NOS
11/16/10
C73.9

[page 2 of 3]
Date of Procedure:

Date of Receipt:

Date of Report:

Billing Type:

INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

Multinodular goiter.

Specimens Submitted:

1: Thyroid, thyroidectomy

DIAGNOSIS:

1. Thyroid, thyroidectomy:

Tumor Type:

Papillary carcinoma, follicular variant
with oncocytic features

Histologic Grade:

Well differentiated

Mitotic Activity:

Mild to moderate

Tumor Necrosis:

Not identified

Tumor Location:

arising in a parasitic nodule

Tumor Size:

Greatest diameter is 5 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Separate focus of papillary microcarcinoma measuring 0.35cm in right lobe. psammoma bodies also present.

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

[page 3 of 3]
Exhibits chronic lymphocytic thyroiditis
Parathyroid Glands:
Not identified

Lymph Nodes:
Two benign lymph nodes (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "total thyroid" and consists of a thyroid weighing 74.5 G. The right lobe measures 5 x 3.8 x 1.5 Cm, the left lobe measures 6.5 x 3 x 1 Cm and the isthmus measures 2.2 x 2 x 0.8 Cm. A 5 x 4.5 x 4 cm mass is attached to the right lobe by a fibrous "stalk" measuring 2.2 x 1.8 x 0.3 cm. The mass is covered by a thin fibrous capsule. The external surface is covered by a thin fibrous capsule. The posterior surface of the thyroid, the mass and the posterior surface of the stalk are inked black and the anterior surface of the thyroid and the stalk is inked blue. Sectioning reveals that the mass is not connected through the thyroid parenchyma. The cut surface of the mass is tan with focal hemorrhage, homogeneous and fleshy. Sections through the remaining tissue reveal diffuse vague tan nodularity without a dominant nodule. Representative sections of the specimen are submitted for TPS, cytogenetics and flow cytometry and a photograph has been taken. The remaining tissue is serially sectioned. The thyroid is submitted entirely from superior to inferior. The tumor is representatively submitted.

Summary of sections:

T - tumor mass
TS - tumor with the "stalk"
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: Thyroid, thyroidectomy

Block	Sect. Site	PCs
2	IS	2
8	LL	8
8	RL	8
5	T	5
1	TS	1

Source: NCI Genomic Data Commons file eca989ff-a6ed-498b-b6d6-973ba8ba5298 (TCGA-DJ-A13R.1A4EFF12-E96A-4D1E-8BA7-C126E7333211.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).